Surgical pathology report (de-identified scan), TCGA case TCGA-61-1738, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1738-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: SMALL BOWEL TUMOR, EXCISION –
PAPILLARY SEROUS ADENOCARCINOMA.

PART 2: OMENTUM, OMENTECTOMY –
PAPILLARY SEROUS ADENOCARCINOMA WITH ABUNDANT NECROSIS AND WITH FOCAL AREAS OF CLEAR CELL PATTERN.

PART 3: UTERUS AND ADNEXA, 126 GRAMS, TOTAL ABDOMINAL HYSTERECTOMY –

- A. PAPILLARY SEROUS ADENOCARCINOMA ARISING ON AN ENDOMETRIAL POLYP AND LIMITED TO THE POLYP, NO MYOMETRIAL INVASION SEEN. SEE COMMENT.
- B. VASCULAR LYMPHATIC SPACE INVASION NOTED. AT THE BASE OF THE POLYP.
- C. PAPILLARY SEROUS ADENOCARCINOMA PRESENT ON SEROSAL SURFACE OF THE UTERUS.
- D. RIGHT OVARY WITH PAPILLARY SEROUS ADENOCARCINOMA INVOLVING OVARIAN SURFACE AND OVARIAN STROMA. SEE COMMENT.
- E. SEROSAL NODULE WITH PAPILLARY SEROUS ADENOCARCINOMA AND EXTENSIVE NECROSIS.
- F. SMALL SEROSAL NODULE WITH FIBROSIS AND HYALINIZATION ASSOCIATED WITH TWO SMALL TUMOR FRAGMENTS, PROBABLY FLOATERS.
- G. CHRONIC CERVICITIS WITH NABOTHIAN CYST AND ATROPHIC CHANGES.
- H. SENESCENT ENDOMETRIUM WITH SECRETORY CHANGES.
- I. LEIOMYOMATA, SUBMUCOSAL, UP TO 1.3 CM IN DIAMETER.
- J. LEFT OVARY WITH PHYSIOLOGIC CHANGES AND ENDOSALPINGOSIS.
- K. LEFT FALLOPIAN TUBE WITH NO SIGNIFICANT ABNORMALITIES.
- L. RIGHT FALLOPIAN TUBE WITH GRANULOMATOUS REACTION OF FOLDS ASSOCIATED WITH MICROCALCIFICATIONS, NO UNEQUIVOCAL TUMOR IDENTIFIED.

PART 4: LYMPH NODE, LEFT, ILIAC –
ONE LYMPH NODE NEGATIVE FOR METASTATIC TUMOR (0/1).

PART 5: LYMPH NODE, LEFT, EXTERNAL ILIAC –
ADIPOSE TISSUE, NO LYMPH NODE SEEN.

PART 6: LYMPH NODE, RIGHT, COMMON ILIAC –
ONE LYMPH NODE NEGATIVE FOR METASTATIC TUMOR (0/1).

PART 7: LYMPH NODE, RIGHT, EXTERNAL ILIAC –
ONE LYMPH NODE NEGATIVE FOR METASTATIC TUMOR (0/1).

PART 8 APPENDIX AND TUMOR –
VERMIFORM APPENDIX WITH FIBROUS OBLITERATION AND ATTACHED PAPILLARY SEROUS ADENOCARCINOMA NODULES.

PART 9: PARACOLIC MASS, RIGHT –
PAPILLARY SEROUS ADENOCARCINOMA.

PART 10: PARASPLENIC TUMOR –
PAPILLARY SEROUS ADENOCARCINOMA MASS.

COMMENT:

The entire left ovary was submitted for microscopic examination. Recuts were made from the original section of the left ovary looking for tumor metastasis. A small fragment of tumor is present detached from the ovarian surface. Therefore, I consider that fragment to be a contaminant. WT 1 immunostains were performed on the tumor present in the endometrial polyp as well as in tumor present in the wall of the intestine and the omentum. Their results are controversial, and therefore, they are not contributory to determine if the tumor in the abdomen and right ovary are metastatic from the endometrial tumor or vice versa, or they are two synchronous independent primary tumors. Morphologically, the tumors are very similar.

Source: NCI Genomic Data Commons file 436103d8-771d-4bb8-92ab-d04358c1450c (TCGA-61-1738.05898C76-9832-4724-ADA5-FF47EB3838B5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).